TCGA case TCGA-L9-A7SV — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Candler. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/54e90433-5218-4d83-848f-f995ecba2a63

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,298 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed Disodium; Days to treatment start: 41 days; Days to treatment end: 104 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 111 days; Disease response: Tumor Free.
- Days to follow up: 565 days (1.5 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- DLCO (% of predicted): 55; FEV1/FVC after bronchodilator (%): 40; FEV1/FVC before bronchodilator (%): 38; FEV1 after bronchodilator (% of reference): 45; FEV1 before bronchodilator (% of reference): 40.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 93; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 1990.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-L9-A7SV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 220 mg.
  Slide TCGA-L9-A7SV-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-L9-A7SV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-L9-A7SV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 565 days; disease-specific survival: no event (censored), 565 days; disease-free interval: no event (censored), 565 days; progression-free interval: no event (censored), 565 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-L9-A7SV-01A-11D-A396-01): tumor purity 0.83, ploidy 3.06, whole-genome doublings 1.
